Somatic mutation profile of tumor specimen ALCH-B25B-TTP1-A (aliquot ALCH-B25B-TTP1-A-3-0-D-A774-36) from ALCHEMIST case ALCH-B25B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,600 days).
Specimen ALCH-B25B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1c7c500-b962-4d2e-af61-8e50760bc751.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B25B-NB1-A (Blood Derived Normal), aliquot ALCH-B25B-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28e61725-c303-4f59-9424-460cbcc3da64

The open-access MAF lists 327 somatic variants for this specimen: 229 protein-altering or splice-affecting, 61 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 61, Intron 15, Nonsense Mutation 9, RNA 8, Splice Site 7, 5'UTR 6, Frame Shift Del 5, 5'Flank 5, Splice Region 3, Frame Shift Ins 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COX15 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28939711, CM030209; ClinVar: pathogenic; called by muse, mutect2
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 43/246 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LTBP3 | c.3910_*6del | Nonstop Mutation (DEL) | VAF 3/22 reads (14%) | catalogued as rs779871744; ClinVar: likely pathogenic; called by mutect2, pindel
- RARS2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 22/116 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs774923951, CM156894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 25/59 reads (42%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.77G>C p.R26T | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55396395; called by muse, mutect2, varscan2
- AC013489.1 | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1271852550; called by muse, mutect2, varscan2
- ADAM2 | c.1400A>G p.E467G | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.281); catalogued as COSV55867135; called by muse, mutect2, varscan2
- ADAM29 | c.761A>T p.K254I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV63660890; called by muse, mutect2, varscan2
- ANTXRL | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs184963887; called by muse, mutect2
- ARHGEF4 | c.1723C>A p.L575M | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58131022; called by muse, mutect2, varscan2
- ATP13A5 | c.2004del p.N669Ifs*8 | Frame Shift Del (DEL) | VAF 37/209 reads (18%) | catalogued as COSV100665464; called by mutect2, pindel, varscan2
- ATP1A2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs866493442; called by muse, mutect2, varscan2
- BBS7 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.1); catalogued as rs1290320900; called by muse, mutect2, varscan2
- C19orf47 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs140539184; called by muse, mutect2, varscan2
- CEP131 | c.1909-2A>T p.X637_splice (on ENST00000269392 / NM_001319228.2; = p.X634_splice on NM_014984.4) | Splice Site (SNP) | VAF 17/34 reads (50%) | catalogued as rs1426378668; called by muse, mutect2, varscan2
- CFAP46 | c.5971G>T p.G1991C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs541680936, COSV99584532, COSV99585634; called by muse, mutect2, varscan2
- CHRM2 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV57769577; called by muse, mutect2, varscan2
- CREBZF | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs367799926, COSV52629523; called by muse, mutect2, varscan2
- DNAH7 | c.7441G>A p.A2481T | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs778772421; called by muse, mutect2, varscan2
- DSCAML1 | c.3089G>T p.R1030L (on ENST00000321322; = p.R970L on NM_020693.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as rs758642341, COSV58395976; called by muse, mutect2, varscan2
- ECHDC3 | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs754435622; called by muse, mutect2, varscan2
- EPB41L5 | c.830A>G p.K277R | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1189272148; called by muse, mutect2, varscan2
- ERCC6 | c.3115A>G p.R1039G | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100876324; called by muse, mutect2, varscan2
- ERICH3 | c.3728T>C p.L1243P | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100443188; called by muse, mutect2, varscan2
- FLG2 | c.6790C>A p.H2264N | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs770971156; called by muse, mutect2, varscan2
- HOXD3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs190587708; called by mutect2, varscan2
- IQCA1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746383347; called by muse, mutect2
- ITGA1 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV50890861; called by muse, mutect2, varscan2
- KCTD16 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as rs760934349, COSV72578873; called by muse, mutect2, varscan2
- LAMB4 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52726350, COSV99063904; called by muse, mutect2, varscan2
- MAPKAPK2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043183855, COSV54316084; called by muse, mutect2, varscan2
- MCM3AP | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as rs745557447; called by mutect2, varscan2
- ME2 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382972962; called by muse, mutect2, varscan2
- MUC16 | c.41222C>A p.A13741D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as rs1285588878, COSV101109841, COSV66692001; called by muse, mutect2, varscan2
- MYH11 | c.1213C>G p.R405G | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55555399; called by muse, mutect2, varscan2
- MYH7 | c.1459C>G p.Q487E | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100805853; called by muse, mutect2
- MYO18B | c.1828G>T p.V610F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs1249535960; called by muse, mutect2, varscan2
- NAALAD2 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV100428138; called by muse, mutect2, varscan2
- NLGN4X | c.2300C>G p.S767W | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV52019787; called by muse, mutect2, varscan2
- NLRP5 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as rs1396086410, COSV66764017; called by muse, mutect2, varscan2
- OR13F1 | c.304T>A p.Y102N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV58251387; called by muse, mutect2, varscan2
- OR14A2 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63573579; called by muse, mutect2, varscan2
- OR2B6 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1321541031, COSV55128830, COSV99773718; called by muse, mutect2, varscan2
- OR2L3 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV63454631; called by mutect2, varscan2
- OR8G5 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV100422441; called by muse, mutect2, varscan2
- PCDHB2 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782163761, COSV99523143; called by muse, varscan2
- PCDHB2 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs949003962, COSV99523144; called by muse, varscan2
- PCDHB8 | c.1389G>C p.E463D | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99175200; called by muse, mutect2
- PCDHGA2 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs770680401, COSV53893398, COSV53904096; called by muse, mutect2, varscan2
- PLA2G6 | c.967G>T p.V323L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as rs1456513786; called by muse, mutect2, varscan2
- RAG1 | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs753962790; called by muse, mutect2, varscan2
- RARS2 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV65760509; called by muse, mutect2, varscan2
- RB1 | c.2107-2A>G p.X703_splice | Splice Site (SNP) | VAF 24/104 reads (23%) | catalogued as CS890135, COSV57316167; called by muse, mutect2, varscan2
- RNF2 | c.853A>G p.T285A | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs780104917; called by muse, mutect2, varscan2
- SBNO2 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1382998961; called by muse, varscan2
- SERPINA7 | c.1136C>A p.T379N | Missense Mutation (SNP) | VAF 25/319 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.247); catalogued as COSV100568255; called by muse, mutect2
- SHROOM4 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs142827776; called by muse, mutect2, varscan2
- SLC23A2 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs776326380; called by muse, mutect2, varscan2
- SLC33A1 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 60/381 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV63947476; called by muse, mutect2, varscan2
- SLC35G2 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101262114; called by muse, mutect2, varscan2
- SLCO1B1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs901600794; called by muse, mutect2, varscan2
- STRN4 | c.1764C>T p.S588= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as rs1271348332; called by muse, varscan2
- SYN2 | c.13del p.L5Cfs*19 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as COSV70285198; called by mutect2, pindel, varscan2
- TAAR2 | c.338T>G p.L113R (on ENST00000367931 / NM_001033080.1; = p.L68R on NM_014626.3) | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.485); catalogued as COSV51579180; called by muse, mutect2, varscan2
- TBC1D10C | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56703083; called by muse, mutect2, varscan2
- TECPR2 | c.2528G>T p.R843L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs765981384; called by muse, mutect2, varscan2
- TNR | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.271); catalogued as rs749572126, COSV99692087; called by muse, mutect2, varscan2
- TPM1 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1555409132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM49B | c.154T>C p.C52R | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs753156718, COSV60320949; called by muse, mutect2
- TRRAP | c.10296G>A p.M3432I (on ENST00000359863 / NM_001244580.1; = p.M3403I on NM_003496.3) | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100722941; called by mutect2, varscan2
- TSC22D2 | c.1343A>G p.Q448R | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs768579073; called by muse, mutect2, varscan2
- TYW1B | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs556042271; called by muse, mutect2, varscan2
- UTRN | c.1388A>G p.H463R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455065164; called by muse, mutect2
- VPS8 | c.2466G>C p.E822D (on ENST00000625842 / NM_001349294.1; = p.E820D on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV54979755, COSV54986300; called by muse, mutect2, varscan2
- ZBED9 | c.2417C>A p.P806Q | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV71729746; called by muse, mutect2, varscan2
- ZNF579 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as rs552565318; called by muse, mutect2, varscan2
- ZNF585A | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.783); catalogued as COSV53062734; called by muse, mutect2, varscan2
- ZNF704 | c.1136G>A p.R379K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1209567886; called by muse, mutect2, varscan2
- ZRANB3 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51505394; called by muse, mutect2
- ABTB2 | c.594dup p.A199Rfs*55 | Frame Shift Ins (INS) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- ACER3 | c.498G>A p.W166* | Nonsense Mutation (SNP) | VAF 76/352 reads (22%) | called by muse, mutect2, varscan2
- ACRV1 | c.278A>T p.H93L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ADGRL3 | c.4186C>A p.L1396M (on ENST00000506720 / NM_001322402.2; = p.L1285M on NM_015236.6) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ADPRHL1 | c.308C>A p.T103N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AHNAK | c.8438del p.G2813Dfs*30 | Frame Shift Del (DEL) | VAF 36/181 reads (20%) | called by mutect2, pindel, varscan2
- AMOT | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AMZ1 | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- AOX1 | c.3566T>C p.M1189T | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ARHGAP31 | c.2242_2243insGCCAG p.D748Gfs*12 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- ARHGAP42 | c.2340G>T p.R780S | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- ARID5A | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ARMCX2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP2B2 | c.3025C>A p.R1009S (on ENST00000352432; = p.R975S on NM_001683.5) | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- ATP6V0A2 | c.2278A>T p.S760C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BABAM2 | c.680+2T>C p.X227_splice | Splice Site (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- BRCC3 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRWD3 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2
- C2CD4A | c.625A>G p.S209G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CALD1 | c.1808G>A p.R603K (on ENST00000361675 / NM_033138.4; = p.R348K on NM_004342.7) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CD6 | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDX1 | c.525C>A p.Y175* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- CHD5 | c.2697C>T p.N899= | Splice Region (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- COL4A5 | c.1390G>T p.D464Y | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.467); called by muse, mutect2
- DLG3 | c.1523C>A p.A508D (on ENST00000374360 / NM_021120.4; = p.A171D on NM_020730.3) | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- DMTF1 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- DNAH14 | c.1163A>C p.K388T (on ENST00000445597; = p.K369T on NM_001145154.3) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH7 | c.1564del p.I522* | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | called by mutect2, pindel, varscan2
- DPY19L2 | c.953+1G>C p.X318_splice | Splice Site (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- DSG1 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- EDARADD | c.379A>C p.I127L (on ENST00000334232 / NM_145861.4; = p.I117L on NM_080738.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- EHD2 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.029); called by mutect2, varscan2
- ERFE | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FAM135B | c.1084C>A p.L362M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM200A | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- FAM214A | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.7523A>G p.N2508S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FBXL5 | c.1549A>T p.T517S | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGA | c.2176G>T p.V726F | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBP9 | c.812G>C p.C271S | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- FLNA | c.1531G>T p.G511C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FMN2 | c.1298C>A p.P433Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRMPD1 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- FRMPD4 | c.1997C>G p.P666R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- FZD7 | c.173C>G p.T58R | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- GABRA2 | c.1147G>C p.V383L | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GALNS | c.836A>T p.D279V | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GDF10 | c.798C>A p.Y266* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- GFRA2 | c.1328C>A p.P443H | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GLI3 | c.4687A>G p.S1563G | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- GPD1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2
- GPR50 | c.46T>A p.C16S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2
- GREB1 | c.2905C>T p.H969Y | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- GUCA2B | c.153G>T p.W51C | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- HCFC1 | c.5326C>A p.Q1776K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.9); called by muse, mutect2
- HDAC6 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- HDGFL1 | c.475C>G p.R159G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2
- HMCN1 | c.10881G>C p.E3627D | Missense Mutation (SNP) | VAF 29/420 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.462); called by muse, mutect2
- IFNGR1 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGSF11 | c.955A>G p.S319G (on ENST00000393775 / NM_001015887.3; = p.S318G on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2
- INPP5D | c.3410C>T p.P1137L (on ENST00000445964 / NM_001017915.3; = p.P1136L on NM_005541.5) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- IQSEC2 | c.2542G>C p.G848R (on ENST00000642864 / NM_001111125.3; = p.G643R on NM_015075.2) | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGB5 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA3 | c.418T>G p.F140V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF5C | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LPL | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRP1B | c.7148G>C p.S2383T | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- LRP8 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LTBP1 | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- MAMDC4 | c.540G>T p.W180C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MOK | c.743C>A p.P248H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MRPL17 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MUC17 | c.2309C>T p.T770I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- MYH14 | c.4055G>T p.G1352V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MYO10 | c.4943A>G p.Y1648C | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAALAD2 | c.1846G>T p.G616* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- NAV3 | c.3181G>T p.A1061S | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NEUROD4 | c.33G>T p.M11I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, varscan2
- NEUROD4 | c.235A>T p.K79* | Nonsense Mutation (SNP) | VAF 19/163 reads (12%) | called by muse, varscan2
- NMBR | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- NOX1 | c.784T>C p.F262L | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- NPAT | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- OGDHL | c.1723C>G p.P575A | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR14A2 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2L3 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- OR2L8 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OR2M4 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- OR4D6 | c.896A>G p.Q299R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- OR51A4 | c.310T>A p.F104I | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- PARP14 | c.2865A>T p.K955N | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PCDHB3 | c.2204A>C p.Q735P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, varscan2
- PDE4B | c.1819C>A p.H607N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDGFRA | c.2449C>A p.R817S | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDHA1 | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PLAGL2 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PLBD2 | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R21 | c.1615G>C p.V539L | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP2R3B | c.879G>T p.Q293H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- PPP3CA | c.1082-1G>A p.X361_splice | Splice Site (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- PRKCH | c.1074C>G p.I358M | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PRPF8 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR23A | c.332G>C p.R111P | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- PRR35 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PRUNE2 | c.4160C>A p.A1387D | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PTPN21 | c.766T>G p.W256G | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, varscan2
- RAPGEF1 | c.1790G>A p.S597N | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RB1 | c.2622dup p.L875Tfs*4 | Frame Shift Ins (INS) | VAF 68/356 reads (19%) | called by mutect2, pindel, varscan2
- RHPN2 | c.1801-2A>G p.X601_splice | Splice Site (SNP) | VAF 30/141 reads (21%) | called by muse, mutect2, varscan2
- RIF1 | c.3333A>T p.K1111N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- RPRD1A | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, varscan2
- SLC11A1 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC25A5 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SLC25A53 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SLCO4C1 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- SLF2 | c.1495T>C p.S499P | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- SLFN13 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SLITRK5 | c.1343T>A p.I448N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SORCS1 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSX5 | c.226del p.V76Sfs*24 (on ENST00000347757 / NM_175723.1; = p.V117Sfs*24 on NM_021015.4) | Frame Shift Del (DEL) | VAF 48/224 reads (21%) | called by mutect2, varscan2
- STAB2 | c.1608+2T>C p.X536_splice | Splice Site (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- STARD8 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SURF2 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1L | c.2440A>T p.N814Y | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TBC1D32 | c.1256A>T p.Y419F | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBC1D32 | c.1018T>A p.L340M | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- TBC1D3F | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.464); called by mutect2, varscan2
- TCEAL2 | c.263C>G p.S88* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- TCIRG1 | c.1208T>G p.M403R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- TERF1 | c.827A>G p.D276G | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TFAP2D | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TMEM175 | c.629_631del p.S210del | In Frame Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- TNKS | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2
- TRADD | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRHDE | c.2935A>T p.K979* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | called by muse, varscan2
- TRIM7 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TTN | c.8562G>C p.Q2854H (on ENST00000591111; = p.Q2808H on NM_003319.4) | Missense Mutation (SNP) | VAF 19/188 reads (10%) | PolyPhen benign (0.015); called by muse, mutect2
- UNKL | c.1013A>T p.Q338L | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNKL | c.925G>C p.A309P | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USF3 | c.6544A>G p.N2182D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13D | c.5899G>T p.V1967L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VPS33A | c.1782A>T p.K594N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VWA5A | c.2117T>C p.M706T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- WWC2 | c.3477G>C p.Q1159H | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- XRCC5 | c.1796G>T p.R599L | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZBTB39 | c.508A>T p.R170* | Nonsense Mutation (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- ZBTB46 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX4 | c.1304T>C p.M435T | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZRANB1 | c.198A>G p.I66M | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZRANB3 | c.1158G>T p.K386N | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ABI3BP | c.270G>T p.P90= | Silent (SNP) | VAF 53/249 reads (21%) | called by muse, mutect2, varscan2
- ADCY2 | c.1167G>A p.G389= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- ATP7A | c.342A>G p.T114= | Silent (SNP) | VAF 11/217 reads (5%) | called by muse, mutect2
- ATRN | c.1539C>T p.A513= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs569482622; called by muse, mutect2, varscan2
- C9orf50 | c.111G>T p.P37= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1457918020; called by muse, mutect2, varscan2
- CD82 | c.54G>A p.L18= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV57037197; called by muse, mutect2, varscan2
- CHST1 | c.195C>A p.I65= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs764636490; called by muse, mutect2, varscan2
- COL19A1 | c.1131A>G p.E377= | Silent (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- CPE | c.565C>A p.R189= | Silent (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- CROCC2 | c.1095T>A p.T365= | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- CYP1A2 | c.1140C>T p.S380= | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- DCBLD1 | c.1389G>A p.L463= | Silent (SNP) | VAF 23/235 reads (10%) | called by muse, mutect2, varscan2
- DKK1 | c.354A>G p.R118= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- EFNA2 | c.369G>A p.P123= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- ERBB3 | c.3150A>G p.P1050= | Silent (SNP) | VAF 90/412 reads (22%) | called by muse, mutect2, varscan2
- FAM151B | c.258A>G p.L86= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as rs761830086; called by muse, mutect2, varscan2
- FGF10 | c.580A>C p.R194= | Silent (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- FGF10 | c.258C>A p.T86= | Silent (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2
- FLNC | c.4017C>T p.P1339= | Silent (SNP) | VAF 12/110 reads (11%) | called by mutect2, varscan2
- FSTL5 | c.1812C>A p.P604= | Silent (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2, varscan2
- GAS7 | c.276G>T p.R92= (on ENST00000432992 / NM_201433.2; = p.R32= on NM_201432.2) | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as rs745979895; called by muse, mutect2, varscan2
- H4C9 | c.234G>A p.K78= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs1228638767; called by muse, mutect2, varscan2
- HCFC1 | c.5325G>A p.L1775= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- HDAC6 | c.3513G>T p.P1171= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs782380536; called by muse, mutect2, varscan2
- IGLV3-16 | c.27C>A p.P9= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2
- ILDR2 | c.1020C>T p.S340= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- IMPG2 | c.36G>T p.L12= | Silent (SNP) | VAF 36/440 reads (8%) | catalogued as COSV99516619; called by muse, mutect2
- KRT81 | c.699C>A p.I233= | Silent (SNP) | VAF 64/243 reads (26%) | called by muse, mutect2, varscan2
- LRRC7 | c.3324G>A p.L1108= (on ENST00000651989 / NM_001370785.2; = p.L1075= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- MAGEA6 | c.411G>A p.G137= | Silent (SNP) | VAF 33/183 reads (18%) | catalogued as COSV61448992; called by muse, mutect2, varscan2
- MASP1 | c.1434C>G p.S478= | Silent (SNP) | VAF 30/265 reads (11%) | called by muse, mutect2, varscan2
- MBL2 | c.237A>T p.P79= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- NLRP7 | c.780C>T p.V260= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs186762492; called by muse, mutect2, varscan2
- OR8D2 | c.642C>T p.V214= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs267602758; called by muse, mutect2, varscan2
- OTUD6A | c.237G>A p.L79= | Silent (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- PAPPA2 | c.3690T>A p.R1230= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, varscan2
- PCDHB11 | c.1377C>T p.F459= | Silent (SNP) | VAF 69/188 reads (37%) | catalogued as COSV61311456; called by muse, mutect2, varscan2
- PKHD1L1 | c.7761G>A p.R2587= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs781576322; called by muse, mutect2, varscan2
- PLB1 | c.300G>A p.Q100= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as rs146883246; called by muse, mutect2, varscan2
- PLSCR4 | c.531G>A p.R177= | Silent (SNP) | VAF 87/474 reads (18%) | called by muse, mutect2, varscan2
- PLXNA1 | c.510G>A p.A170= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1029396948, COSV52529491, COSV99302012; called by muse, mutect2
- PPA1 | c.532C>T p.L178= | Silent (SNP) | VAF 23/220 reads (10%) | called by muse, mutect2, varscan2
- RBM19 | c.213G>T p.R71= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- REG1B | c.480T>C p.F160= | Silent (SNP) | VAF 9/164 reads (5%) | called by muse, mutect2
- SCN7A | c.1611C>T p.L537= | Silent (SNP) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- SLC37A2 | c.1089C>T p.T363= | Silent (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2, varscan2
- SOD3 | c.453C>T p.V151= | Silent (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- SOX17 | c.594C>T p.H198= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs761826744; called by mutect2, varscan2
- SYNE1 | c.25392A>G p.E8464= (on ENST00000367255 / NM_182961.4; = p.E8416= on NM_033071.3) | Silent (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- SYNE1 | c.528C>A p.I176= (on ENST00000367255 / NM_182961.4; = p.I183= on NM_033071.3) | Silent (SNP) | VAF 41/314 reads (13%) | catalogued as COSV99557569; called by muse, mutect2, varscan2
- TIGIT | c.525G>T p.V175= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- TRIM64C | c.576G>A p.E192= | Silent (SNP) | VAF 55/324 reads (17%) | called by muse, mutect2, varscan2
- TTC4 | c.285C>T p.Y95= | Silent (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.36537G>C p.V12179= (on ENST00000591111; = p.V4755= on NM_003319.4) | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- TTYH1 | c.27C>T p.P9= | Silent (SNP) | VAF 12/42 reads (29%) | called by mutect2, varscan2
- UBE3C | c.864G>A p.A288= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs896770773; called by muse, mutect2
- UHRF1BP1L | c.849A>G p.T283= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- VGLL1 | c.138C>T p.S46= | Silent (SNP) | VAF 7/129 reads (5%) | catalogued as COSV101034536; called by muse, mutect2
- WDR64 | c.1821T>A p.A607= | Silent (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- ZBTB39 | c.507T>C p.D169= | Silent (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- ZNF891 | c.1566A>G p.G522= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1483791939; called by muse, mutect2, varscan2
- AC016582.1 | chr19:37824559 G>C | 3'Flank (SNP) | VAF 60/220 reads (27%) | called by muse, mutect2, varscan2
- AC103996.1 | chr15:93821097 A>T | 3'Flank (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1047-3047A>G | Intron (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- ADGRL1 | c.-9G>T | 5'UTR (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- AKAP9 | c.5698-2938G>C | Intron (SNP) | VAF 32/165 reads (19%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848533 T>A | 5'Flank (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- AP1S3 | c.*39_*42del | 3'UTR (DEL) | VAF 16/134 reads (12%) | catalogued as rs200257231; called by pindel, varscan2
- ARFGAP1 | c.835-238G>A | Intron (SNP) | VAF 43/105 reads (41%) | called by muse, mutect2, varscan2
- CNGB3 | c.-17G>T | 5'UTR (SNP) | VAF 27/330 reads (8%) | called by muse, mutect2
- CYP2C8 | c.1150-24G>A | Intron (SNP) | VAF 23/204 reads (11%) | called by muse, mutect2, varscan2
- DAAM2 | c.1845+106T>C | Intron (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- DENND5B | c.128-45063C>T | Intron (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- FAM169B | n.355A>T | RNA (SNP) | VAF 10/70 reads (14%) | catalogued as rs756600170; called by muse, mutect2, varscan2
- FAM182A | n.841T>C | RNA (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- FUNDC2P2 | n.306G>T | RNA (SNP) | VAF 54/176 reads (31%) | called by muse, mutect2, varscan2
- IL12A | c.421-13T>A | Intron (SNP) | VAF 110/402 reads (27%) | called by muse, mutect2, varscan2
- LGI4 | c.628+52G>T | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- LINC02035 | n.119C>T | RNA (SNP) | VAF 25/92 reads (27%) | catalogued as rs577757341; called by muse, mutect2, varscan2
- LPIN1 | c.-5A>G | 5'UTR (SNP) | VAF 6/30 reads (20%) | catalogued as rs769824579; called by muse, mutect2
- MDGA2 | c.281-41510C>T | Intron (SNP) | VAF 19/130 reads (15%) | catalogued as rs754566953; called by muse, mutect2, varscan2
- OR51F5P | n.604C>A | RNA (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- PPP1R1B | chr17:39622102 C>T | 5'Flank (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- PRSS40A | n.142-2251C>A | Intron (SNP) | VAF 36/292 reads (12%) | called by muse, varscan2
- PSG6 | c.706+60G>A | Intron (SNP) | VAF 27/158 reads (17%) | catalogued as rs754988913; called by muse, mutect2, varscan2
- PVALEF | c.-429G>C | 5'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- RGS8 | c.-127G>A | 5'UTR (SNP) | VAF 54/221 reads (24%) | catalogued as rs1209679715, COSV99276436; called by muse, mutect2, varscan2
- RIPOR2 | c.-14G>A | 5'UTR (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- SLC4A8 | c.-112+11707G>T | Intron (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- SLC7A6OS | chr16:68311012 G>A | 5'Flank (SNP) | VAF 8/45 reads (18%) | catalogued as rs1457851093; called by muse, varscan2
- SLCO4A1 | chr20:62642141 G>A | 5'Flank (SNP) | VAF 3/15 reads (20%) | catalogued as rs1006811316; called by muse, varscan2
- SNCAIP | c.1592+35T>A | Intron (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.1569G>A | RNA (SNP) | VAF 43/259 reads (17%) | called by muse, mutect2, varscan2
- SSPOP | n.6691A>T | RNA (SNP) | VAF 7/39 reads (18%) | catalogued as COSV50487578; called by muse, mutect2, varscan2
- SSPOP | n.15663C>A | RNA (SNP) | VAF 14/60 reads (23%) | called by muse, varscan2
- TTN | c.10361-4874T>A | Intron (SNP) | VAF 79/468 reads (17%) | catalogued as COSV60139335; called by muse, mutect2, varscan2
- TVP23C | chr17:15565746 G>T | 5'Flank (SNP) | VAF 77/311 reads (25%) | catalogued as rs746068279; called by muse, mutect2, varscan2
- ZNF446 | c.713-61A>T | Intron (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
